Gene-level copy-number profile of tumor specimen TCGA-XF-A8HG-01A from TCGA case TCGA-XF-A8HG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.6 years (25,421 days).
Specimen TCGA-XF-A8HG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.007a3b5e-75ba-4990-8d49-5ff398939eb0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A8HG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4198514-3f7b-4781-a64a-12d45cae92a5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 13; copy number 2: 7,459; copy number 3: 24,789; copy number 4: 13,457; copy number 5: 7,063; copy number 6: 2,247; copy number 7: 3,129; copy number 10: 280; copy number 11: 1,370; copy number 34: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A8HG-01A-11D-A363-01): tumor purity 0.84, ploidy 3.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,791 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–159,233,377, 3,014 genes, copy number 7 (broad region; genes not listed).
- chr8:36,378,069–38,996,824, 71 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:39,018,615–39,018,683, 1 gene, copy number 10: SNORD38D.
- chr8:42,391,624–145,066,685, 1,578 genes, copy number 10–11 (broad region; genes not listed).
- chr20:760,080–1,002,311, 5 genes, copy number 7: SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4.
- chr20:5,937,228–6,220,759, 16 genes, copy number 7: TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3.
- chr20:9,835,556–10,673,999, 19 genes, copy number 7: AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870.
- chr20:10,696,949–10,765,286, 2 genes, copy number 7: LINC01752, AL135937.1.
- chr20:12,243,308–13,169,103, 9 genes, copy number 7: AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1.
- chr20:16,670,641–17,226,146, 12 genes, copy number 7: Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3.
- chr20:17,887,363–17,903,861, 2 genes, copy number 7: AL035045.1, RNU6-192P.
- chr20:20,389,530–22,074,654, 34 genes, copy number 7 (within-gene range 4–7): RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1, AL109807.1, LINC01432.
- chr20:32,052,197–32,439,319, 12 genes, copy number 34 (within-gene range 5–34): HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1.
- chr20:35,278,907–35,621,094, 16 genes, copy number 7: EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
